Somatic mutation profile of tumor specimen TCGA-WN-A9G9-01A (aliquot TCGA-WN-A9G9-01A-12D-A36X-10) from TCGA case TCGA-WN-A9G9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-WN-A9G9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fba6e96-0b1c-41b5-a69e-d220d4d4d6dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WN-A9G9-10A (Blood Derived Normal), aliquot TCGA-WN-A9G9-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62c1a94d-67d7-4f5f-89d7-68b4e3fd2257

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 35, Silent 17, Frame Shift Ins 4, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.266T>A p.L89H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS7 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101183310; called by muse, mutect2
- AHCTF1 | c.1412T>C p.V471A (on ENST00000366508; = p.V445A on NM_015446.5) | Missense Mutation (SNP) | VAF 97/482 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100404566; called by muse, mutect2, varscan2
- ATM | c.3153+2T>A p.X1051_splice | Splice Site (SNP) | VAF 23/223 reads (10%) | catalogued as COSV53764179; called by muse, mutect2, varscan2
- CAMK2D | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99594987; called by muse, mutect2
- CFLAR | c.528A>T p.Q176H | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV100010002; called by muse, mutect2
- CSMD1 | c.7570G>T p.E2524* (on ENST00000520002; = p.E2523* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV100154737; called by muse, mutect2, varscan2
- DDX17 | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV99318441; called by muse, mutect2, varscan2
- DENND2A | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99327178; called by muse, mutect2, varscan2
- DOK5 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs751913418, COSV52822329; called by muse, mutect2
- ERCC6 | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV100876330; called by muse, mutect2, varscan2
- FKTN | c.1254C>A p.Y418* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV99795648; called by muse, mutect2
- FLOT1 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99458370; called by muse, mutect2
- GNPTAB | c.3488C>A p.T1163K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100172496; called by muse, mutect2, varscan2
- GRAMD1A | c.5T>A p.F2Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV100526468; called by muse, mutect2
- HNRNPA1 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99267949; called by muse, mutect2, varscan2
- IMMT | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs778087708, COSV99607706; called by muse, mutect2, varscan2
- INPP4A | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50813949, COSV99305638; called by muse, mutect2, varscan2
- KANSL1L | c.2239A>C p.N747H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99911102; called by muse, mutect2, varscan2
- MAT2A | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99290263; called by muse, mutect2, varscan2
- MED1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV100328225; called by muse, mutect2, varscan2
- MUC17 | c.10262C>T p.T3421I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as COSV100075483; called by muse, mutect2, varscan2
- MUCL3 | c.995C>G p.P332R (on ENST00000304311; = p.P1208R on NM_080870.4) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as rs1331390205, COSV100424473; called by muse, mutect2, varscan2
- NEURL4 | c.2816A>T p.Y939F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.893); catalogued as rs966832326, COSV100223371; called by muse, mutect2
- NUMBL | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV99425172; called by muse, mutect2, varscan2
- OSBPL11 | c.872C>G p.T291R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs762989677, COSV99954608; called by muse, mutect2, varscan2
- PNRC1 | c.834T>G p.N278K | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100260070; called by muse, mutect2, varscan2
- PTK2B | c.2867A>T p.K956M | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53560251; called by muse, mutect2, varscan2
- RBM10 | c.2133G>C p.M711I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100238413; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99541702; called by muse, mutect2
- SYPL2 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100881589; called by muse, mutect2
- TOB1 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99278962; called by muse, mutect2, varscan2
- TOR1B | c.639C>T p.L213= | Splice Region (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99400352; called by muse, mutect2
- TRIM71 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV101070525; called by muse, mutect2, varscan2
- USH1G | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV58883881; called by muse, mutect2, varscan2
- USP34 | c.6136G>C p.D2046H | Missense Mutation (SNP) | VAF 31/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1183884241, COSV101277288; called by muse, mutect2
- USP42 | c.2483C>G p.A828G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs377506977, COSV60360223; called by muse, mutect2, varscan2
- YAE1 | c.512G>C p.C171S | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99785122; called by muse, mutect2, varscan2
- ZFYVE16 | c.3203T>C p.L1068P | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100566675; called by muse, mutect2, varscan2
- ALDOC | c.885_897del p.W296Sfs*35 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- BRAF | c.697dup p.T233Nfs*17 | Frame Shift Ins (INS) | VAF 8/94 reads (9%) | called by mutect2, pindel
- CENPE | c.4878del p.E1627Nfs*7 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ERRFI1 | c.1187dup p.L397Tfs*3 | Frame Shift Ins (INS) | VAF 20/178 reads (11%) | called by mutect2, pindel, varscan2
- GNA13 | c.371del p.S124Cfs*26 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- RNF39 | c.979dup p.R327Kfs*33 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- SPOCK3 | c.535del p.C179Vfs*56 | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4125_4136del p.E1376_D1379del | In Frame Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- TARBP1 | c.3851_3852dup p.S1285Lfs*8 | Frame Shift Ins (INS) | VAF 43/348 reads (12%) | called by mutect2, pindel, varscan2
- ZNF226 | c.664_687del p.K222_Y229del | In Frame Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel
- ARAF | c.1191C>T p.A397= | Silent (SNP) | VAF 5/135 reads (4%) | catalogued as rs1402792816, COSV99283494; called by muse, mutect2
- CEP68 | c.1503C>A p.S501= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99561362; called by muse, mutect2
- COL5A3 | c.1029T>C p.D343= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99319929; called by muse, mutect2
- EPHB4 | c.1488G>T p.G496= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs747173949, COSV100639689; called by muse, mutect2, varscan2
- GPR141 | c.744C>T p.Y248= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100550510; called by muse, mutect2, varscan2
- HELZ | c.1554T>A p.S518= | Silent (SNP) | VAF 39/297 reads (13%) | catalogued as COSV100699115; called by muse, mutect2, varscan2
- LRRC32 | c.1152C>T p.A384= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV99477399; called by muse, mutect2
- LRRC6 | c.888G>A p.G296= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs1467063591, COSV99138772; called by muse, mutect2, varscan2
- LYST | c.5178T>C p.F1726= | Silent (SNP) | VAF 40/417 reads (10%) | catalogued as COSV101090459; called by muse, mutect2
- OSMR | c.1842G>A p.E614= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99953669; called by muse, mutect2, varscan2
- PCDHB7 | c.1665C>T p.N555= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs782725222, COSV50753531, COSV99176308; called by muse, mutect2
- PDE8A | c.1066A>C p.R356= | Silent (SNP) | VAF 44/458 reads (10%) | catalogued as COSV100052498; called by muse, mutect2
- PPP4R3B | c.738A>G p.A246= | Silent (SNP) | VAF 20/195 reads (10%) | catalogued as COSV99702842; called by muse, mutect2
- RYR1 | c.8655G>A p.T2885= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as COSV100615186, COSV62115774; called by muse, mutect2
- TP53RK | c.444G>A p.Q148= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100927789; called by muse, mutect2, varscan2
- TRIM71 | c.9G>T p.S3= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs779603354, COSV101070526; called by muse, mutect2, varscan2
- USP24 | c.2973C>A p.A991= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as COSV99601215; called by muse, mutect2, varscan2
